Gene-level copy-number profile of tumor specimen ALCH-B34A-TTP1-A from ALCHEMIST case ALCH-B34A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 51.7 years (18,894 days).
Specimen ALCH-B34A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5ce38ade-c833-4f26-b51f-3d457266c729.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B34A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/ae38678e-3bb4-4e07-a49d-5f6c5e3cf6d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 21,505; copy number 2: 33,299; copy number 3: 2,310; copy number 4: 678; copy number 5: 229; copy number 6: 38; copy number 7: 114; copy number 8: 26; copy number 9: 74.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,978,943–43,996,528, 2 genes (within-gene range 0–2): B4GALT2, CCDC24.
- chr2:148,295,656–148,296,679, 1 gene (within-gene range 0–2): USP12P2.
- chr2:241,754,793–241,755,740, 1 gene (within-gene range 0–1): AC114730.2.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:90,184,634–90,261,708, 3 genes: RNU6-712P, PROS2P, HSPE1P19.
- chr4:49,096–50,124, 1 gene: BNIP3P41.
- chr4:3,244,369–3,271,738, 1 gene: MSANTD1.
- chr4:18,418,662–18,888,662, 2 genes: AC093898.1, AC093871.1.
- chr5:50,396,192–50,443,248, 1 gene: EMB.
- chr5:70,860,285–71,025,339, 5 genes: CDH12P1, SERF1A, SMN1, AC139834.1, NAIP.
- chr7:76,521,611–76,541,459, 4 genes: AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr8:11,576,257–11,582,817, 1 gene: LINC00208.
- chr10:46,369,113–46,453,306, 5 genes: FAM25BP, AC244230.1, ANXA8L1, LINC00842, HNRNPA1P33.
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–1): EMX2.
- chr10:124,461,823–124,617,888, 2 genes (within-gene range 0–1): LHPP, RPS10P18.
- chr12:37,575,587–38,167,631, 7 genes: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359.
- chr12:130,651,342–130,669,233, 1 gene (within-gene range 0–1): AC095350.1.
- chr13:70,459,464–70,459,570, 1 gene: RNU6-54P.
- chr15:20,228,620–20,359,166, 3 genes (within-gene range 0–1): RHPN2P1, CHEK2P2, AC026495.1.
- chr15:25,170,723–25,225,284, 30 genes (within-gene range 0–1): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:28,857,882–29,118,315, 4 genes (within-gene range 0–1): AC174071.1, AC174469.1, APBA2, AC127522.1.
- chr15:41,503,637–41,557,435, 3 genes: LTK, RPAP1, ELOCP2.
- chr15:64,739,891–64,825,668, 3 genes: RBPMS2, MIR1272, PIF1.
- chr15:76,336,773–76,344,365, 3 genes: ISL2, AC027243.1, AC027243.2.
- chr16:46,469,341–46,621,379, 5 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1.
- chr16:67,723,070–67,832,148, 3 genes (within-gene range 0–1): RANBP10, AC010530.1, TSNAXIP1.
- chr17:16,922,915–16,972,118, 2 genes: TBC1D27P, TNFRSF13B.
- chr17:18,511,262–18,521,252, 1 gene (within-gene range 0–1): USP32P2.
- chr17:63,695,888–63,702,670, 2 genes (within-gene range 0–2): LIMD2, AC046185.3.
- chr19:4,472,297–4,518,465, 2 genes: HDGFL2, PLIN4.
- chr19:17,719,242–17,734,513, 2 genes: MAP1S, AC008761.1.
- chr19:19,512,418–19,515,548, 1 gene: TSSK6.
- chr20:5,482,736–5,535,889, 4 genes: LINC00654, LINC01729, RPS18P1, AL109935.1.
- chr21:23,960,569–23,968,747, 1 gene: AP000477.2.
- chr22:35,540,831–35,553,999, 1 gene: RASD2.
- chr22:42,617,840–42,649,392, 2 genes: CYB5R3, ATP5MGL.
- chr22:46,576,012–46,679,790, 1 gene: GRAMD4.
- chr22:49,960,768–49,964,072, 2 genes: PIM3, MIR6821.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 462 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:22,118,236–22,357,154, 2 genes, copy number 5: RAPGEF5, RNA5SP227.
- chr7:23,562,459–31,119,572, 173 genes, copy number 5–9 (broad region; genes not listed).
- chr7:105,530,209–108,905,226, 57 genes, copy number 5–8: AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2.
- chr10:61,901,684–62,304,033, 3 genes, copy number 6: ARID5B, RTKN2, LINC02621.
- chr10:62,350,006–62,350,297, 1 gene, copy number 6: RN7SL591P.
- chr10:74,744,386–77,638,369, 44 genes, copy number 6–7 (within-gene range 6–9): FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321.
- chr10:81,875,194–82,987,179, 5 genes, copy number 5 (within-gene range 3–5): NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P.
- chr20:63,090,806–64,327,972, 79 genes, copy number 5 (broad region; genes not listed).
- chr21:30,880,644–33,588,706, 69 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:38,155,549–39,172,106, 22 genes, copy number 5 (within-gene range 3–5): KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2.
- chr22:15,489,990–15,578,006, 7 genes, copy number 5: YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1.

Autosomal genes at a single copy (total copy number 1): 19,341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
